FM case AD14491 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms.
https://portal.gdc.cancer.gov/cases/4d3732d4-06e1-4653-8dcd-587187097f9e

Male, 79.9 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3); specimen biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 52% (pathologist estimate recorded by GDC). Sample type: Tumor.
